CPTAC case C3N-01340 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/010ddf79-3e32-42d3-a17c-82c64a19325d

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Dead; Days to death: 1,388 days (3.8 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 72.2 years (26,376 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Residual disease: R1; Last known disease status: Tumor free; Days to last known disease status: 1,388 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,264 days (3.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (4 entries)
- Days to follow up: 302 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 689 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,009 days (2.8 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,264 days (3.5 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 77 kg; Height: 175 cm; BMI: 25.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01340-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 169 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01340-21: Section location: Larynx; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-01340-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 122 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01340-22: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-01340-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 127 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01340-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
